Surgical pathology report (de-identified scan), TCGA case TCGA-HD-8635, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-HD-8635-01A (Primary Tumor).

[page 1 of 2]
Final Diagnosis

Right tongue, partial glossectomy (with frozen section):

Squamous cell carcinoma, moderately differentiated, keratinizing, measures 1.2 cm in greatest microscopic dimension.

Maximum depth of invasion is 6 mm.

Margins of resection are free of tumor (closest margin is deep, which is 9 mm away).

No lymphatic/vascular invasion identified.

No perineural invasion identified.

Immunohistochemical stain for p16 will be performed and results issued in an addendum report.

Right neck level 2 sentinel lymph node, excision:

Metastatic carcinoma involving 1 lymph node (1/1).

Focus of metastatic carcinoma measures 3.5 mm in greatest microscopic dimension.

No extracapsular extension is identified.

AJCC tumor classification: pT1,pN1(sn).

Stage III Acc

Clinical Information

Tongue cancer.

Frozen Section Diagnosis

Time In No Time Out given

Right partial glossectomy. 4.5 cm anterior to posterior, 3.5 cm superior to inferior, and 2.5 cm depth. Inked superior black, inferior orange, anterior red, posterior green, and deep blue. Margins show tumor close to posterior margin grossly. Mucosal ulceration 1 cm in greatest dimension.

FSA1 Superior and inferior margins:

No tumor noted.

FSA2 Deep and posterior margins:

No tumor noted.

FSA3 Inferior margin:

No tumor noted. NTF

Gross Description

[page 2 of 2]
previously inked superior black, inferior orange, anterior red, posterior green, and deep blue. Three portions of the specimen have been submitted for frozen section in cassettes "FSA1-FSA3." "A1-A3," random sections of full-thickness of specimen to include ulcerated mucosa.

"B, Sentinel node #1 right level 2." Received is a 1.4 x 0.6 x 0.5 cm lymph node, which is tinged with blue dye. The specimen will be bisected and submitted in toto. "B," all, multiple levels.

Performing Lab

Source: NCI Genomic Data Commons file 9a924413-671f-4408-b9ce-4ed274ad9249 (TCGA-HD-8635.D10A73DC-8178-413B-8BE3-D3E10B82B6D8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).